CPTAC case C3L-03965 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d53bb16c-51b6-4ed0-a1aa-bc88a7894e2c

Demographics
Sex at birth: male; Race: white; Year of birth: 1964; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 54.1 years (19,760 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2b; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,422 days (3.9 years); Progression or recurrence: no; Days to last follow up: 1,422 days (3.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.2 cm; Lymph node involvement: Positive; Lymph nodes positive: 7; Lymph nodes tested: 13; Margin status: Uninvolved.

Follow-up (5 entries)
- Days to follow up: 507 days (1.4 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 779 days (2.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,123 days (3.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,123 days (3.1 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 1,422 days (3.9 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 107 kg; Height: 170 cm; BMI: 37.02.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Cigarettes per day: 40; Tobacco smoking onset year: 1998; Tobacco smoking quit year: 2018; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 20.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03965-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 318 mg; Time between clamping and freezing: 35 minutes; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03965-22: Section location: Right lung; Percent tumor nuclei: 50; Percent necrosis: 20.
- Sample C3L-03965-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 246 mg; Time between clamping and freezing: 39 minutes; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03965-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
